Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A19A, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A19A-06A (Metastatic).

Melanoma, NOS

PATIENT HISTORY:

No clinical history is given.

PRE-OP DIAGNOSIS: Melanoma back.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Wide excision melanoma back, bilateral axillary sentinel node biopsy.

8720/3 12/14/10 lw

Site code: back, subcutaneous tissue C496

FINAL DIAGNOSIS:**PART 1: SKIN AND SUBCUTANEOUS TISSUE, BACK, WIDE EXCISION -**

- A. METASTATIC MALIGNANT MELANOMA, 4 CM. IN SKIN (DERMIS) AND SUBCUTANEOUS TISSUE WITH EXTENSIVE ANGIOLYMPHATIC INVASION (see comment).
- B. MARGINS OF RESECTION FREE OF TUMOR.

PART 2: SOFT TISSUE, ADDITIONAL DEEP MARGIN, RESECTION -

- A. FIBROADIPOSE TISSUE WITH NO SPECIFIC PATHOLOGIC CHANGE.
- B. NEGATIVE FOR MALIGNANCY.

PART 3: LYMPH NODE, SENTINEL #1, LEFT, EXCISION -

BENIGN ONE (1) LYMPH NODE, NEGATIVE FOR METASTATIC MALIGNANT MELANOMA (0/1) (see comment).

PART 4: LYMPH NODE, SENTINEL #1, RIGHT, EXCISION -

BENIGN ONE (1) LYMPH NODE, NEGATIVE FOR METASTATIC MALIGNANT MELANOMA (0/1) (see comment).

PART 5: LYMPH NODE, NON-SENTINEL, RIGHT, EXCISION -

BENIGN ONE (1) LYMPH NODE, NEGATIVE FOR METASTATIC MALIGNANT MELANOMA (0/1).

PART 6: LYMPH NODE, SENTINEL #2, RIGHT, EXCISION -

BENIGN FIVE (5) LYMPH NODES, NEGATIVE FOR METASTATIC MELANOMA (0/5) (see comment).

COMMENT:

The neoplasm in part 1 shows several adjacent nodules and a dominant neoplasm in most of the sections with neural, perineural and angiolymphatic extension. The morphology is pleomorphic at places with spindle cells and also some osteoclast-like giant cells. No epidermal involvement is seen. The sentinel lymph node immunohistochemical protocol is performed on parts 3,4 and 6 with S100, HMB45, tyrosinase, CD68 and Melan A. The melanoma marker stains are negative and confirms the above diagnosis of negative nodes.

Please see [REDACTED]

Source: NCI Genomic Data Commons file 6565a469-32ae-48d5-be05-73914cd85ccd (TCGA-ER-A19A.B48FFC2C-4D9A-4451-B237-3B004D773260.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).